Somatic mutation profile of cancer-model specimen HCM-BROD-0873-C43-85B (Adherent Cell Line, passage 8; aliquot HCM-BROD-0873-C43-85B-01D-A881-36), derived from the primary tumor of HCMI case HCM-BROD-0873-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 66.8 years (24,401 days).
Specimen HCM-BROD-0873-C43-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ef56256-1141-49a1-b8e5-742a6687dde1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0873-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0873-C43-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9803457-139e-4f2e-aa08-3f6074c4bb91

The open-access MAF lists 760 somatic variants for this specimen: 480 protein-altering or splice-affecting, 253 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 430, Silent 253, Nonsense Mutation 35, Intron 17, Splice Region 6, Frame Shift Del 6, 5'Flank 3, Splice Site 2, RNA 2, 3'UTR 2, 3'Flank 2, Translation Start Site 1.

Variants (750 of 760; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs796052065, CM154496; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 121/323 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 142/318 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs771100656; called by muse, mutect2, varscan2
- ABCB5 | c.3577G>T p.V1193L (on ENST00000404938 / NM_001163941.2; = p.V748L on NM_178559.6) | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as rs745507733; called by mutect2, varscan2
- ACSM2B | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 90/600 reads (15%) | catalogued as rs370210894; called by muse, mutect2, varscan2
- ADAMTS13 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 248/371 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs587701622, COSV63020852; called by muse, mutect2, varscan2
- ADGRF4 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 222/436 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51952806; called by muse, mutect2, varscan2
- AGXT | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 81/373 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as CM970066; called by muse, mutect2, varscan2
- AHR | c.1364C>T p.S455F | Missense Mutation (SNP) | VAF 134/384 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1348476694; called by muse, mutect2, varscan2
- AKAP4 | c.445A>G p.R149G | Missense Mutation (SNP) | VAF 183/268 reads (68%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV62074090; called by muse, mutect2, varscan2
- AL645922.1 | c.1289C>T p.P430L | Missense Mutation (SNP) | VAF 72/916 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100191402; called by muse, mutect2
- AOC1 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 224/490 reads (46%) | catalogued as rs1022684348; called by muse, mutect2, varscan2
- APBB1IP | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1239954436, COSV66132958; called by muse, mutect2, varscan2
- APOB | c.4162C>T p.R1388C | Missense Mutation (SNP) | VAF 100/393 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as rs267599185, COSV51928488; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOH | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 192/515 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1034195006; called by muse, mutect2, varscan2
- AREG | c.711A>T p.E237D | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1259763460; called by muse, mutect2
- ASIC5 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72232548; called by muse, mutect2, varscan2
- ASTN1 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56090345, COSV99923687; called by muse, mutect2, varscan2
- ASTN1 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as rs868490770, COSV56066359, COSV99923691; called by muse, mutect2, varscan2
- ATP2B2 | c.1681G>A p.G561S (on ENST00000352432; = p.G527S on NM_001683.5) | Missense Mutation (SNP) | VAF 84/570 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs780965218; called by muse, mutect2, varscan2
- BATF3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 231/537 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767493633; called by muse, mutect2, varscan2
- BNC1 | c.2556G>T p.E852D | Missense Mutation (SNP) | VAF 206/478 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61757787; called by muse, mutect2, varscan2
- C10orf71 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 140/370 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1271167930; called by muse, mutect2, varscan2
- C10orf71 | c.4070C>A p.A1357E | Missense Mutation (SNP) | VAF 114/526 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.065); catalogued as COSV60505808; called by mutect2, varscan2
- C3 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 189/450 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV55571730; called by muse, mutect2, varscan2
- CACNA1E | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 77/315 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs751409680, COSV62405324; called by muse, mutect2, varscan2
- CCDC144A | c.3394G>A p.E1132K | Missense Mutation (SNP) | VAF 59/412 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as COSV60698016; called by muse, mutect2, varscan2
- CCR2 | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 158/382 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.084); catalogued as rs1391405321; called by muse, mutect2, varscan2
- CDH22 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 252/687 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1226830817; called by muse, mutect2, varscan2
- CEP131 | c.1612G>A p.E538K (on ENST00000269392 / NM_001319228.2; = p.E535K on NM_014984.4) | Missense Mutation (SNP) | VAF 150/444 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs369438843; called by muse, mutect2, varscan2
- CEP89 | c.2315G>A p.C772Y | Missense Mutation (SNP) | VAF 58/420 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV59868107; called by muse, mutect2
- CHP2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 78/176 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as rs756478431, COSV55649342; called by muse, mutect2, varscan2
- CLNK | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1044868506, COSV57014438; called by muse, mutect2, varscan2
- CNTN6 | c.2173C>T p.P725S | Missense Mutation (SNP) | VAF 93/238 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV63167473, COSV63185871; called by muse, mutect2, varscan2
- COL18A1 | c.2845C>T p.P949S (on ENST00000359759 / NM_130444.3; = p.P714S on NM_030582.4) | Missense Mutation (SNP) | VAF 72/337 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1450327303, COSV62702320; called by muse, mutect2, varscan2
- CSF2RA | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 98/687 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs1418501378, COSV100817539; called by muse, mutect2, varscan2
- CSMD1 | c.10448G>A p.G3483D (on ENST00000520002; = p.G3482D on NM_033225.6) | Missense Mutation (SNP) | VAF 73/356 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1429750842, COSV100151116; called by muse, mutect2, varscan2
- CSMD1 | c.4986C>T p.F1662= (on ENST00000520002; = p.F1661= on NM_033225.6) | Splice Region (SNP) | VAF 22/193 reads (11%) | catalogued as rs750062238; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 140/323 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, varscan2
- CTAGE1 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 107/229 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs560589174; called by muse, mutect2, varscan2
- CYTIP | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 99/300 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99938946; called by muse, mutect2, varscan2
- DDX23 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 81/376 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV57282909; called by muse, mutect2, varscan2
- DIP2B | c.1342T>C p.F448L | Missense Mutation (SNP) | VAF 102/221 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV56584261; called by muse, mutect2, varscan2
- DNAH14 | c.4520G>A p.R1507Q (on ENST00000445597; = p.R1912Q on NM_001367479.1) | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775576952, COSV60736715; called by muse, mutect2, varscan2
- DNAH7 | c.10496C>T p.T3499I | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as rs751299449; called by muse, mutect2, varscan2
- DNAH7 | c.6971G>A p.S2324N | Missense Mutation (SNP) | VAF 155/410 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs992819121; called by muse, mutect2, varscan2
- DOCK9 | c.2977C>T p.H993Y (on ENST00000376460 / NM_001366676.2; = p.H994Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/426 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV59620841; called by muse, mutect2, varscan2
- EEF1D | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 185/471 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs1414453778; called by muse, mutect2, varscan2
- EFCAB12 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 182/602 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV58177472; called by muse, mutect2, varscan2
- EFHB | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 183/405 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs201173584; called by muse, mutect2, varscan2
- EHMT2 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 570/1116 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.125); catalogued as rs777077739; called by muse, mutect2, varscan2
- ERC2 | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 143/351 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV55640574; called by muse, mutect2, varscan2
- ERV3-1 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV51428219; called by muse, mutect2, varscan2
- FAIM | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 176/422 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.892); catalogued as rs574122735, COSV100623853, COSV58159054; called by muse, mutect2, varscan2
- FAP | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 165/387 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.856); catalogued as rs756858958, COSV51860211; called by muse, mutect2, varscan2
- FCRL3 | c.1436C>T p.T479I | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV63840587; called by muse, mutect2, varscan2
- FILIP1 | c.2926C>T p.R976* | Nonsense Mutation (SNP) | VAF 61/327 reads (19%) | catalogued as COSV52741417; called by muse, mutect2, varscan2
- FOXP1 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV59539281; called by muse, mutect2, varscan2
- FREM3 | c.3310G>A p.E1104K | Missense Mutation (SNP) | VAF 102/412 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV61682266; called by muse, mutect2, varscan2
- FSIP2 | c.17320C>T p.Q5774* | Nonsense Mutation (SNP) | VAF 62/273 reads (23%) | catalogued as rs374937631; called by muse, mutect2, varscan2
- GALNT17 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 103/455 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61190698; called by muse, mutect2, varscan2
- GBX2 | c.706G>A p.G236S | Missense Mutation (SNP) | VAF 129/573 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1389171569; called by muse, mutect2, varscan2
- GDE1 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 145/345 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752547994, COSV62060100; called by muse, mutect2, varscan2
- GDF10 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 279/729 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555207505; called by muse, mutect2, varscan2
- GLI1 | c.2801C>T p.S934F | Missense Mutation (SNP) | VAF 72/495 reads (15%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.656); catalogued as COSV57360119; called by muse, mutect2, varscan2
- GOLGA8H | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 45/544 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1341506401; called by muse, mutect2, varscan2
- GPR33 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 160/448 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320364399; called by muse, mutect2, varscan2
- HEATR5B | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 93/407 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1394174125; called by muse, mutect2, varscan2
- HECW2 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 241/653 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs770650499; called by muse, mutect2, varscan2
- HPD | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 75/327 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.17); catalogued as rs202129288, COSV100000180; called by muse, mutect2, varscan2
- HTN1 | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 35/202 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); catalogued as COSV55895541; called by muse, mutect2, varscan2
- HTR3A | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 49/344 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100248555; called by muse, mutect2, varscan2
- IBSP | c.38T>C p.M13T | Missense Mutation (SNP) | VAF 108/271 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as rs570577755; called by muse, mutect2, varscan2
- IDO1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 145/308 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs370075063, COSV99503510; called by muse, mutect2, varscan2
- IL2RG | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.471); catalogued as rs1190663918; called by muse, mutect2, varscan2
- INPPL1 | c.1711C>T p.R571W | Missense Mutation (SNP) | VAF 33/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1165709765, COSV53357878; called by muse, mutect2, varscan2
- IPPK | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 67/374 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs755196776; called by muse, mutect2, varscan2
- IQCA1 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV54495557; called by muse, mutect2, varscan2
- IQGAP3 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 82/370 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1314320250; called by muse, mutect2, varscan2
- ITGA8 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65232864; called by muse, mutect2, varscan2
- IVD | c.901G>A p.V301I (on ENST00000651168; = p.V298I on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/383 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1375901638; called by muse, mutect2, varscan2
- IZUMO2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.391); catalogued as rs761925935, COSV53229350; called by muse, mutect2, varscan2
- KASH5 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 204/474 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV71358055; called by muse, mutect2, varscan2
- KCNK10 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 137/431 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.901); catalogued as rs763733103, COSV56647485; called by muse, mutect2, varscan2
- KCNV1 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.364); catalogued as rs868751450, COSV52087092, COSV52088724; called by muse, mutect2, varscan2
- KIAA1217 | c.3034G>A p.G1012S | Missense Mutation (SNP) | VAF 89/407 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV56814180, COSV56818203; called by muse, mutect2, varscan2
- KIAA2012 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT tolerated (0.32); catalogued as rs760066148; called by muse, mutect2, varscan2
- KIF17 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs756978243; called by muse, mutect2, varscan2
- KIF5A | c.1832T>A p.L611H | Missense Mutation (SNP) | VAF 74/494 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.497); catalogued as COSV99673401; called by muse, mutect2, varscan2
- KIR3DL1 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV58489323; called by muse, mutect2, varscan2
- KRTAP10-3 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 139/617 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.543); catalogued as rs782524222; called by muse, mutect2, varscan2
- LASP1 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 138/375 reads (37%) | catalogued as rs1482520945; called by muse, mutect2, varscan2
- LMOD1 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 243/510 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV66173098; called by muse, mutect2, varscan2
- LMOD3 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 86/380 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV101341996; called by muse, mutect2, varscan2
- LPIN3 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 125/387 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs747237851, COSV64718247; called by muse, mutect2, varscan2
- LRPPRC | c.3854C>T p.P1285L | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.141); catalogued as rs373042003, COSV99580007; called by muse, mutect2, varscan2
- LRRK1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1436826237, COSV52615503; called by muse, mutect2, varscan2
- MAD1L1 | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 249/702 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs201944036; called by muse, mutect2, varscan2
- MAGEA3 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 220/302 reads (73%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV64755890; called by muse, mutect2, varscan2
- MATN1 | c.815C>T p.S272L | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs781588451; called by muse, mutect2, varscan2
- MEOX1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 228/612 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.225); catalogued as rs368570481; called by muse, mutect2, varscan2
- MFGE8 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769108892, COSV51555444, COSV99183935; called by muse, mutect2, varscan2
- MLIP | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 364/695 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1178590734, COSV51430243; called by muse, mutect2, varscan2
- MOV10L1 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 216/527 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1024306111; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 87/521 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778576435, COSV64058120; called by muse, mutect2, varscan2
- MROH2B | c.3905G>A p.R1302Q | Missense Mutation (SNP) | VAF 245/351 reads (70%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.928); catalogued as rs549101906, COSV68184289; called by muse, mutect2, varscan2
- MRPL53 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 135/304 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs779401249, COSV99252030; called by muse, mutect2, varscan2
- MSH4 | c.1428G>A p.M476I | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1013691306; called by muse, mutect2, varscan2
- MUC16 | c.17551C>T p.P5851S | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs267605800, COSV67460962; called by muse, mutect2, varscan2
- MUC4 | c.13378C>T p.P4460S (on ENST00000463781 / NM_018406.7; = p.P224S on NM_004532.6) | Missense Mutation (SNP) | VAF 179/686 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV57789476; called by muse, mutect2, varscan2
- MUC4 | c.10276C>T p.P3426S | Missense Mutation (SNP) | VAF 197/1352 reads (15%) | SIFT tolerated, low confidence (0.74); PolyPhen possibly damaging (0.65); catalogued as COSV57769062; called by muse, mutect2, varscan2
- MYF5 | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 58/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99953293; called by muse, mutect2, varscan2
- MYH4 | c.4429G>A p.E1477K | Missense Mutation (SNP) | VAF 124/474 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs780917874, COSV55113885; called by muse, mutect2, varscan2
- MYO16 | c.945G>A p.M315I | Missense Mutation (SNP) | VAF 70/721 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1347376423, COSV99193481; called by muse, mutect2
- MYO1F | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 266/601 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.426); catalogued as rs201646155, COSV57791852; called by muse, mutect2, varscan2
- MYO9B | c.4439G>A p.G1480E | Missense Mutation (SNP) | VAF 61/460 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1568299637; called by muse, mutect2, varscan2
- MYOCD | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 131/408 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1051971711, COSV100591711; called by muse, mutect2, varscan2
- MYOCD | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 163/490 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1567605374; called by muse, mutect2, varscan2
- MYOM2 | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 148/384 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100037474; called by muse, mutect2, varscan2
- MYOM3 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 97/435 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs755131165; called by muse, mutect2
- MYRIP | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 233/554 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56884749; called by muse, mutect2, varscan2
- NALCN | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 105/383 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.155); catalogued as rs773688637, COSV99216290; called by muse, mutect2, varscan2
- NCKAP5 | c.4016G>A p.G1339E | Missense Mutation (SNP) | VAF 52/392 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.513); catalogued as rs1004766407, COSV58426842; called by muse, mutect2, varscan2
- NDST4 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 110/246 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52126935; called by muse, mutect2, varscan2
- NEO1 | c.866T>A p.L289H | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56071392; called by muse, mutect2, varscan2
- NEU4 | c.1099C>T p.P367S (on ENST00000391969 / NM_001167602.3; = p.P379S on NM_080741.4) | Missense Mutation (SNP) | VAF 342/782 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs776323817; called by muse, mutect2, varscan2
- NLRP11 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 77/333 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs866104256, COSV64086222; called by muse, mutect2, varscan2
- NLRP2 | c.1331G>C p.R444P | Missense Mutation (SNP) | VAF 293/707 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99672146; called by muse, mutect2, varscan2
- NLRP3 | c.825G>A p.M275I | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs779757183; called by muse, mutect2, varscan2
- NLRX1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 62/303 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs775689434, COSV52703240; called by muse, mutect2, varscan2
- NPAS3 | c.331G>A p.D111N (on ENST00000356141 / NM_001164749.2; = p.D81N on NM_022123.3) | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs201385420, COSV58075899, COSV58105393; called by muse, mutect2, varscan2
- NPHS1 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.655); catalogued as COSV62287153, COSV62290133; called by muse, mutect2, varscan2
- NUP188 | c.2983C>T p.R995W | Missense Mutation (SNP) | VAF 231/361 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs1003233120; called by muse, mutect2, varscan2
- NUTM1 | c.2794G>A p.G932R | Missense Mutation (SNP) | VAF 158/399 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs1353793989; called by muse, mutect2, varscan2
- NUTM1 | c.2795G>A p.G932E | Missense Mutation (SNP) | VAF 161/400 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.563); catalogued as COSV100149121; called by muse, mutect2, varscan2
- OR10G4 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 92/714 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100305004, COSV99080552; called by muse, mutect2
- OR10G9 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 78/235 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100901760; called by muse, mutect2
- OR52E2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as COSV58611954; called by muse, mutect2, varscan2
- OR7G2 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 172/438 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1407211337; called by muse, mutect2
- OR8B4 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 115/289 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.111); catalogued as COSV62070052, COSV62070546; called by muse, mutect2, varscan2
- OR9A4 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs535851431, COSV71885566, COSV71886048; called by muse, varscan2
- OR9A4 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV71884912; called by muse, varscan2
- PARP15 | c.1337T>A p.V446D (on ENST00000464300 / NM_001113523.3; = p.V212D on NM_152615.2) | Missense Mutation (SNP) | VAF 63/489 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100116982; called by muse, mutect2, varscan2
- PCIF1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 132/402 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs750052866, COSV65026518; called by muse, mutect2, varscan2
- PGF | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 207/576 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs777134198; called by muse, mutect2, varscan2
- PLIN4 | c.334G>A p.D112N (on ENST00000301286; = p.D127N on NM_001367868.2) | Missense Mutation (SNP) | VAF 231/499 reads (46%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.674); catalogued as rs765437785; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.159); catalogued as COSV62610678; called by muse, mutect2, varscan2
- PNMA2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 85/516 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV99073890; called by muse, mutect2, varscan2
- PPA1 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs1487406557; called by muse, mutect2
- PROS1 | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 60/658 reads (9%) | catalogued as CM163619; called by muse, mutect2
- PTPRS | c.5758C>T p.P1920S | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53638395; called by muse, mutect2, varscan2
- PTPRZ1 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV66437046; called by muse, mutect2, varscan2
- PZP | c.3179C>T p.S1060F | Missense Mutation (SNP) | VAF 153/332 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.722); catalogued as rs914246288; called by muse, varscan2
- RABGAP1L | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 63/362 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770912214, COSV52290098, COSV52306268; called by muse, mutect2, varscan2
- RAI1 | c.2713G>C p.E905Q | Missense Mutation (SNP) | VAF 64/766 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs1233297945; called by muse, mutect2
- RANBP10 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 207/447 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs867080632, COSV58160384, COSV58161287; called by muse, mutect2, varscan2
- RASAL1 | c.289G>C p.D97H | Missense Mutation (SNP) | VAF 145/352 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55655873; called by muse, mutect2, varscan2
- RBM11 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as rs755013691; called by muse, mutect2, varscan2
- RBM11 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 45/342 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as rs1568902564; called by muse, mutect2, varscan2
- RBM20 | c.2131C>T p.R711C | Missense Mutation (SNP) | VAF 112/502 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750763255, COSV65702985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNASE4 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 170/495 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs374269522, COSV59011986; called by muse, mutect2, varscan2
- RNF157 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as rs759017594; called by muse, mutect2, varscan2
- RNPS1 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 175/405 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.968); catalogued as rs1191835522; called by muse, mutect2, varscan2
- RPRD2 | c.3823C>T p.P1275S | Missense Mutation (SNP) | VAF 247/529 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as rs747479817; called by muse, mutect2, varscan2
- SAMD9L | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 80/339 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV59080462, COSV59082718; called by muse, mutect2, varscan2
- SBF1 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 152/590 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62367508; called by muse, mutect2, varscan2
- SCFD2 | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV66371492; called by muse, mutect2, varscan2
- SCN4A | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 210/577 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs886053249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINB4 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868227362, COSV61984277; called by muse, mutect2, varscan2
- SEZ6L | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 236/462 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as rs765777882; called by muse, mutect2, varscan2
- SH3D19 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 85/375 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381746635, COSV58792461; called by muse, mutect2, varscan2
- SH3RF1 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 49/263 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.123); catalogued as rs765883624, COSV52921628; called by muse, varscan2
- SLC46A2 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 67/485 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs530878380; called by muse, mutect2, varscan2
- SLC7A10 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53504027; called by muse, mutect2, varscan2
- SLC8A2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 156/639 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs574343557, COSV52643358; called by muse, mutect2, varscan2
- SLC9C2 | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs1010780200; called by muse, mutect2, varscan2
- SORL1 | c.1603C>T p.P535S | Missense Mutation (SNP) | VAF 150/347 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52762503; called by muse, mutect2, varscan2
- SORL1 | c.4969C>T p.L1657F | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1482327766; called by muse, mutect2, varscan2
- SPEG | c.8540G>A p.R2847Q | Missense Mutation (SNP) | VAF 204/460 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as rs560447047, COSV56669202; called by muse, mutect2, varscan2
- SRGAP3 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 126/564 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1226323955, COSV64533200; called by muse, mutect2, varscan2
- STAB2 | c.6119C>T p.S2040L | Missense Mutation (SNP) | VAF 59/331 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1327618835, COSV66337547; called by muse, mutect2, varscan2
- TARS2 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 210/477 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201039460; called by muse, mutect2, varscan2
- TDO2 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 105/275 reads (38%) | catalogued as rs530115805; called by muse, mutect2, varscan2
- TET2 | c.5437C>T p.Q1813* | Nonsense Mutation (SNP) | VAF 154/386 reads (40%) | catalogued as rs1315434367; called by muse, mutect2, varscan2
- TGM7 | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV101476837; called by muse, mutect2, varscan2
- TLL1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1452918005, COSV50269380; called by muse, mutect2, varscan2
- TLR10 | c.803A>G p.H268R | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs757373016; called by muse, mutect2, varscan2
- TMEM102 | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 65/779 reads (8%) | catalogued as COSV99548561; called by muse, mutect2
- TMEM102 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 65/783 reads (8%) | catalogued as rs747439202; called by muse, mutect2
- TNFSF14 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 186/408 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.2); catalogued as rs879722620; called by muse, mutect2
- TRANK1 | c.7162C>T p.R2388C | Missense Mutation (SNP) | VAF 67/401 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57159986; called by muse, mutect2, varscan2
- TRMT1L | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 120/282 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1214873274; called by muse, mutect2, varscan2
- TRPC4 | c.2771G>A p.G924E (on ENST00000379705 / NM_016179.4; = p.G929E on NM_003306.3) | Missense Mutation (SNP) | VAF 106/344 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58999192, COSV59001644; called by muse, mutect2, varscan2
- TRPV1 | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 141/378 reads (37%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs201663686; called by muse, mutect2, varscan2
- TXNRD3 | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 120/705 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs1031055662; called by muse, mutect2, varscan2
- VCL | c.3391C>T p.P1131S (on ENST00000211998 / NM_014000.3; = p.P1063S on NM_003373.4) | Missense Mutation (SNP) | VAF 54/266 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1226232250; called by muse, mutect2, varscan2
- VPS39 | c.1753C>T p.R585C (on ENST00000348544 / NM_001301138.2; = p.R574C on NM_015289.5) | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs191703716, COSV58791433; called by muse, mutect2, varscan2
- WASL | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV56136484; called by muse, mutect2, varscan2
- WDR64 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 212/446 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs759519562; called by muse, mutect2, varscan2
- WNT4 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.823); catalogued as rs1257786771; called by muse, mutect2, varscan2
- XPO1 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 56/317 reads (18%) | catalogued as COSV99065710; called by muse, varscan2
- ZBTB14 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 162/355 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs767606188, COSV63696300; called by muse, mutect2, varscan2
- ZDHHC13 | c.1073G>A p.W358* | Nonsense Mutation (SNP) | VAF 33/347 reads (10%) | catalogued as rs1239126649; called by muse, mutect2
- ZDHHC19 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 110/335 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200886120, COSV99579642; called by muse, mutect2, varscan2
- ZG16B | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 193/451 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.412); catalogued as rs751882900, COSV66525872; called by muse, mutect2, varscan2
- ZHX2 | c.694G>A p.V232M | Missense Mutation (SNP) | VAF 140/601 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV58717163; called by muse, mutect2
- ZNF20 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 55/439 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.061); catalogued as COSV100502912; called by muse, mutect2, varscan2
- ZNF217 | c.2942C>T p.P981L | Missense Mutation (SNP) | VAF 202/532 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1021240005, COSV56602931; called by muse, mutect2, varscan2
- ZNF474 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 100/140 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV56946764; called by muse, mutect2, varscan2
- ZNF568 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 122/527 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs778837491, COSV71278977; called by muse, mutect2, varscan2
- ZNF726 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.648); catalogued as rs1243180625, COSV58044217; called by muse, mutect2, varscan2
- ZSCAN30 | c.35C>A p.A12D | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV104412100; called by muse, mutect2, varscan2
- ABCA3 | c.4256G>A p.G1419E | Missense Mutation (SNP) | VAF 124/514 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA7 | c.2551C>T p.L851= | Splice Region (SNP) | VAF 66/299 reads (22%) | called by muse, varscan2
- ABCC6 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 149/399 reads (37%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- AC011479.1 | c.15C>G p.F5L | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- ACOT4 | c.1241A>G p.Q414R | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ACSM2A | c.1369C>T p.Q457* (on ENST00000219054; = p.Q378* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 68/147 reads (46%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.3365del p.N1122Tfs*3 | Frame Shift Del (DEL) | VAF 150/385 reads (39%) | called by mutect2, pindel, varscan2
- ADAR | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 107/270 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAT1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 52/375 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AGBL1 | c.3059G>A p.G1020D | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); called by muse, mutect2
- AHNAK | c.7687A>T p.K2563* | Nonsense Mutation (SNP) | VAF 180/438 reads (41%) | called by muse, mutect2, varscan2
- AHNAK2 | c.16115A>G p.N5372S | Missense Mutation (SNP) | VAF 196/492 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AK9 | c.4555G>A p.V1519I | Missense Mutation (SNP) | VAF 141/264 reads (53%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AL645922.1 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 72/910 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALDOB | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 235/356 reads (66%) | called by muse, mutect2, varscan2
- ANKRD12 | c.5929G>T p.V1977L | Missense Mutation (SNP) | VAF 109/254 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANKRD2 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARC | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 175/493 reads (35%) | called by muse, mutect2, varscan2
- AREG | c.712C>T p.R238* | Nonsense Mutation (SNP) | VAF 38/408 reads (9%) | called by muse, mutect2
- AREL1 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 60/521 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ARHGAP17 | c.2476C>T p.L826F (on ENST00000289968 / NM_001006634.3; = p.L748F on NM_018054.6) | Missense Mutation (SNP) | VAF 48/472 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.082); called by muse, mutect2
- ATAD5 | c.4331C>T p.T1444I | Missense Mutation (SNP) | VAF 159/487 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ATP13A2 | c.3427C>T p.P1143S | Missense Mutation (SNP) | VAF 99/372 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2B2 | c.1682G>A p.G561D (on ENST00000352432; = p.G527D on NM_001683.5) | Missense Mutation (SNP) | VAF 85/579 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AXIN2 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 106/867 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- B3GALT1 | c.469T>A p.L157I | Missense Mutation (SNP) | VAF 203/482 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- BBS9 | c.2149C>T p.Q717* (on ENST00000242067 / NM_001348036.1; = p.Q677* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 157/395 reads (40%) | called by muse, mutect2, varscan2
- BRCA2 | c.10109G>A p.R3370K | Missense Mutation (SNP) | VAF 160/479 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BRSK1 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 107/589 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- C19orf18 | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 131/310 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C3orf56 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 148/501 reads (30%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- C5orf34 | c.1459T>C p.F487L | Missense Mutation (SNP) | VAF 147/209 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CC2D2A | c.2338G>A p.G780R | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CCDC85B | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 67/450 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- CCR5 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 175/450 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- CDH13 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 41/227 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH2 | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDHR5 | c.261G>A p.E87= | Splice Region (SNP) | VAF 202/416 reads (49%) | called by muse, mutect2, varscan2
- CDK10 | c.884C>T p.A295V (on ENST00000353379 / NM_052988.5; = p.A224V on NM_052987.4) | Missense Mutation (SNP) | VAF 233/509 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CDKN2D | c.144C>T p.V48= | Splice Region (SNP) | VAF 69/285 reads (24%) | called by muse, mutect2, varscan2
- CELSR1 | c.4324G>A p.V1442M | Missense Mutation (SNP) | VAF 70/486 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CEP250 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 231/604 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- CFAP221 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 110/278 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP47 | c.7525C>T p.Q2509* | Nonsense Mutation (SNP) | VAF 115/160 reads (72%) | called by muse, mutect2, varscan2
- CFAP54 | c.8383G>T p.D2795Y | Missense Mutation (SNP) | VAF 68/377 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- CFAP54 | c.8656G>A p.D2886N | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CMYA5 | c.9938C>T p.T3313I | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CNGA3 | c.1755G>A p.M585I | Missense Mutation (SNP) | VAF 167/398 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CNN3 | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 100/302 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL5A1 | c.3539G>A p.G1180E | Missense Mutation (SNP) | VAF 208/300 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL5A3 | c.3400G>A p.D1134N | Missense Mutation (SNP) | VAF 209/501 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- COL6A6 | c.2764G>A p.E922K | Missense Mutation (SNP) | VAF 241/763 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- COL9A3 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 214/634 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- COX7B | c.143_159del p.F48Yfs*44 | Frame Shift Del (DEL) | VAF 84/158 reads (53%) | called by mutect2, pindel, varscan2
- CRLF3 | c.904G>A p.G302S | Missense Mutation (SNP) | VAF 123/411 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- CRYGD | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 36/244 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD1 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- CSMD2 | c.3287-1G>A p.X1096_splice | Splice Site (SNP) | VAF 133/432 reads (31%) | called by muse, mutect2, varscan2
- CTAGE8 | c.2171C>T p.P724L | Missense Mutation (SNP) | VAF 62/397 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- CTNNA3 | c.1704G>A p.M568I | Missense Mutation (SNP) | VAF 36/250 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CYP2E1 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 55/345 reads (16%) | called by muse, mutect2, varscan2
- DENND4A | c.5031G>A p.W1677* | Nonsense Mutation (SNP) | VAF 54/422 reads (13%) | called by muse, mutect2, varscan2
- DHX57 | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 87/478 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DLC1 | c.2941C>T p.P981S (on ENST00000276297 / NM_001348081.2; = p.P544S on NM_006094.5) | Missense Mutation (SNP) | VAF 79/334 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNHD1 | c.9604C>T p.L3202F | Missense Mutation (SNP) | VAF 91/409 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- DST | c.10735C>T p.Q3579* | Nonsense Mutation (SNP) | VAF 75/618 reads (12%) | called by muse, mutect2, varscan2
- DUOX2 | c.4235A>T p.K1412M | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ECE1 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- EDC4 | c.1522C>T p.L508F | Missense Mutation (SNP) | VAF 61/381 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EIF2AK4 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 137/275 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- EIF2S3B | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 105/512 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- EIF2S3B | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 104/586 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ERAP1 | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAM151A | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM214A | c.2345T>A p.L782* | Nonsense Mutation (SNP) | VAF 31/172 reads (18%) | called by muse, mutect2, varscan2
- FAR2 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 67/348 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAR2 | c.1078C>G p.P360A | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FDX1 | c.64_73del p.G22Cfs*14 | Frame Shift Del (DEL) | VAF 80/550 reads (15%) | called by mutect2, pindel, varscan2
- FNDC1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 195/333 reads (59%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- FOXA1 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 143/471 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FREM2 | c.4390C>T p.P1464S | Missense Mutation (SNP) | VAF 157/469 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRYL | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FSIP2 | c.15798G>C p.K5266N | Missense Mutation (SNP) | VAF 41/304 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- GALNT15 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 82/574 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GALNT15 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 81/572 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GATAD2B | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 88/684 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GLB1L | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 103/463 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNA15 | c.910G>A p.D304N | Missense Mutation (SNP) | VAF 163/360 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOLGA3 | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 146/622 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GOLGA8H | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 45/546 reads (8%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPR17 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 87/640 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.239); called by muse, varscan2
- GPR45 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 130/585 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- GPRC5A | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 58/507 reads (11%) | called by muse, mutect2, varscan2
- GPRC6A | c.406T>A p.Y136N | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GRID2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 139/309 reads (45%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIN3A | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 57/383 reads (15%) | called by muse, mutect2, varscan2
- H3Y1 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 44/269 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HAVCR1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 197/340 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- HCRTR2 | c.1280C>A p.T427N | Missense Mutation (SNP) | VAF 164/574 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- HERC1 | c.6541G>A p.G2181R | Missense Mutation (SNP) | VAF 89/271 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOOK1 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- HSPB11 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IDO1 | c.688C>T p.L230F | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFNL2 | c.195A>T p.E65D | Missense Mutation (SNP) | VAF 136/305 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGLV8-61 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQGAP1 | c.4148C>T p.T1383I | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- IQGAP3 | c.4569C>T p.S1523= | Splice Region (SNP) | VAF 54/249 reads (22%) | called by muse, mutect2, varscan2
- IRS1 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IRS4 | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 77/358 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IRS4 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ITPR3 | c.1702C>T p.R568C | Missense Mutation (SNP) | VAF 271/525 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAG2 | c.3236C>T p.S1079F | Missense Mutation (SNP) | VAF 187/506 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- KAT6B | c.895T>C p.C299R | Missense Mutation (SNP) | VAF 70/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNC4 | c.1851G>T p.Q617H | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNC4 | c.1852C>G p.H618D | Missense Mutation (SNP) | VAF 37/347 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNMA1 | c.2234C>T p.S745F | Missense Mutation (SNP) | VAF 48/328 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- KDM4F | c.1406G>A p.R469K | Missense Mutation (SNP) | VAF 68/297 reads (23%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLF3 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 155/370 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- KNTC1 | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- KRT17 | c.952C>T p.L318F | Missense Mutation (SNP) | VAF 56/388 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KRT4 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 34/244 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- LCT | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 59/286 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- LGI1 | c.1487A>T p.Y496F | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- LGI4 | c.1176G>A p.W392* | Nonsense Mutation (SNP) | VAF 67/482 reads (14%) | called by muse, mutect2, varscan2
- LGI4 | c.1175G>A p.W392* | Nonsense Mutation (SNP) | VAF 68/483 reads (14%) | called by muse, mutect2, varscan2
- LILRA2 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 75/375 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- LIPJ | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- LRFN5 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 191/544 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- LRRIQ3 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LTBP1 | c.2806G>A p.G936R (on ENST00000404816 / NM_206943.4; = p.G610R on NM_000627.4) | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LTK | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 257/554 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MAP4K1 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 116/438 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP4K1 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 114/438 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAPKBP1 | c.2057C>T p.S686F (on ENST00000456763 / NM_001128608.2; = p.S680F on NM_014994.3) | Missense Mutation (SNP) | VAF 169/394 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MBD5 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 60/375 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- MBOAT4 | c.848G>A p.G283E | Missense Mutation (SNP) | VAF 82/331 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MCHR2 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 71/158 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, varscan2
- MCUB | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MED14 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 86/133 reads (65%) | SIFT tolerated (0.91); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MED24 | c.2446T>G p.C816G | Missense Mutation (SNP) | VAF 119/384 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MLH3 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 68/543 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- MMRN2 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 84/494 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.27601C>T p.P9201S | Missense Mutation (SNP) | VAF 232/576 reads (40%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.058); called by muse, mutect2
- MUC16 | c.15820A>T p.S5274C | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- MUC16 | c.3785C>T p.P1262L | Missense Mutation (SNP) | VAF 109/576 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- MUC7 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 136/661 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.093); called by muse, varscan2
- MYH6 | c.3425C>T p.S1142F | Missense Mutation (SNP) | VAF 185/608 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- MYH8 | c.3116G>A p.G1039E | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- NCKAP5 | c.4015G>A p.G1339R | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- NCKAP5 | c.2456C>T p.P819L | Missense Mutation (SNP) | VAF 146/320 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NDUFAF4 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NEIL3 | c.453A>C p.K151N | Missense Mutation (SNP) | VAF 78/204 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NFRKB | c.3774G>A p.Q1258= (on ENST00000446488 / NM_001143835.2; = p.Q1283= on NM_006165.3) | Splice Region (SNP) | VAF 51/279 reads (18%) | called by muse, mutect2, varscan2
- NISCH | c.2149C>T p.H717Y | Missense Mutation (SNP) | VAF 236/570 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- NIT2 | c.571del p.L191Ffs*35 | Frame Shift Del (DEL) | VAF 164/442 reads (37%) | called by mutect2, pindel, varscan2
- NLRP1 | c.4036T>G p.W1346G (on ENST00000572272 / NM_033004.4; = p.W1302G on NM_014922.5) | Missense Mutation (SNP) | VAF 137/381 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOC3L | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 96/282 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, varscan2
- NONO | c.368A>T p.E123V | Missense Mutation (SNP) | VAF 153/213 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NR5A1 | c.1354C>T p.L452F | Missense Mutation (SNP) | VAF 39/257 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUCKS1 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- OGDHL | c.2306G>A p.G769D | Missense Mutation (SNP) | VAF 119/304 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OPRPN | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 85/414 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- OR10J1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 183/378 reads (48%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5B12 | c.721T>G p.S241A | Missense Mutation (SNP) | VAF 121/309 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- OR8S1 | c.920T>C p.L307S | Missense Mutation (SNP) | VAF 154/381 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR9A4 | c.784C>T p.P262S | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- OS9 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 58/343 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OTOGL | c.1462G>A p.D488N (on ENST00000547103; = p.D479N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- P3H4 | c.326T>C p.V109A | Missense Mutation (SNP) | VAF 105/749 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- PABPC1L | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 199/509 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- PALM3 | c.484G>A p.D162N (on ENST00000340790; = p.D177N on NM_001145028.2) | Missense Mutation (SNP) | VAF 110/531 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PAN3 | c.794A>T p.K265I | Missense Mutation (SNP) | VAF 50/463 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCNT | c.8522C>T p.A2841V | Missense Mutation (SNP) | VAF 193/402 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PDE3A | c.1868C>T p.S623F | Missense Mutation (SNP) | VAF 94/226 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PDGFRA | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 66/331 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGPEP1L | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PKDREJ | c.1640T>C p.V547A | Missense Mutation (SNP) | VAF 75/380 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLAT | c.1665G>A p.W555* | Nonsense Mutation (SNP) | VAF 45/303 reads (15%) | called by muse, mutect2, varscan2
- PLCB1 | c.2494C>G p.L832V | Missense Mutation (SNP) | VAF 95/424 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PLCD3 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 65/805 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2
- PLIN5 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 244/578 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PLXNA2 | c.3185C>A p.T1062K | Missense Mutation (SNP) | VAF 125/280 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- PLXNA2 | c.3184A>T p.T1062S | Missense Mutation (SNP) | VAF 124/278 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PLXNA4 | c.4207G>A p.D1403N | Missense Mutation (SNP) | VAF 203/424 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- POTEJ | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 59/535 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- POU5F1 | c.773A>G p.Q258R | Missense Mutation (SNP) | VAF 99/1100 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- PRADC1 | c.22T>C p.W8R | Missense Mutation (SNP) | VAF 90/405 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); called by muse, mutect2
- PROKR1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 80/445 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PROS1 | c.1401T>G p.I467M | Missense Mutation (SNP) | VAF 60/654 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- PRR36 | c.2854C>T p.L952F | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- PRR36 | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 136/697 reads (20%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PRUNE2 | c.8628_8632del p.E2877Qfs*17 | Frame Shift Del (DEL) | VAF 53/401 reads (13%) | called by mutect2, pindel, varscan2
- RAB11FIP1 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 85/561 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RAB44 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 195/616 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- RAD23A | c.701T>C p.F234S | Missense Mutation (SNP) | VAF 215/480 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RASAL2 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 82/404 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- RASGRF1 | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 81/491 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM19 | c.1152G>A p.W384* | Nonsense Mutation (SNP) | VAF 190/420 reads (45%) | called by muse, mutect2, varscan2
- RBM19 | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 190/421 reads (45%) | called by muse, mutect2, varscan2
- RFC2 | c.773C>T p.P258L (on ENST00000055077 / NM_181471.3; = p.P224L on NM_002914.4) | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGPD4 | c.4930C>T p.P1644S | Missense Mutation (SNP) | VAF 126/255 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIC8B | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 97/450 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- RIMKLA | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.221); called by muse, mutect2
- RNF11 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- RNF112 | c.1133A>T p.D378V | Missense Mutation (SNP) | VAF 147/383 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- RP1 | c.4789G>A p.D1597N | Missense Mutation (SNP) | VAF 70/401 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RPS2 | c.311A>T p.D104V | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- S1PR5 | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 97/655 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SCUBE3 | c.2416G>A p.G806R | Missense Mutation (SNP) | VAF 218/446 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCUBE3 | c.2417G>A p.G806E | Missense Mutation (SNP) | VAF 221/451 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SDAD1 | c.640T>G p.L214V | Missense Mutation (SNP) | VAF 137/322 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SH2D3A | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 225/487 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHLD2 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 48/198 reads (24%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 155/560 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SLC17A3 | c.145A>T p.N49Y | Missense Mutation (SNP) | VAF 60/619 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- SLC2A12 | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A11 | c.367A>T p.K123* | Nonsense Mutation (SNP) | VAF 71/476 reads (15%) | called by muse, varscan2
- SLC39A11 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 76/509 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- SLC39A14 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.232); called by muse, mutect2
- SLC6A14 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 124/184 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- SLC6A20 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 105/232 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SLC9A2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 69/375 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SMARCC2 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 105/226 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SMG5 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 55/410 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SNRPF | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 152/389 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SNTB1 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 48/351 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SORL1 | c.6449G>A p.S2150N | Missense Mutation (SNP) | VAF 87/391 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPAG5 | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 53/414 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPEM1 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 204/577 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- STAG3 | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 42/348 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- SWAP70 | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TCN1 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TENM2 | c.2255G>A p.G752E (on ENST00000518659 / NM_001122679.2; = p.G520E on NM_001080428.3) | Missense Mutation (SNP) | VAF 237/397 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TEX11 | c.251G>A p.G84E (on ENST00000344304; = p.G69E on NM_031276.3) | Missense Mutation (SNP) | VAF 154/224 reads (69%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- THSD7B | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 65/356 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TIAM2 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMC5 | c.2218G>A p.D740N (on ENST00000396229 / NM_001105248.1; = p.D494N on NM_024780.5) | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- TMEM131 | c.4223C>T p.P1408L | Missense Mutation (SNP) | VAF 98/542 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM265 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 88/435 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TNKS | c.3676T>A p.Y1226N | Missense Mutation (SNP) | VAF 175/427 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNN | c.2482G>T p.V828L | Missense Mutation (SNP) | VAF 71/402 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by mutect2, varscan2
- TOM1L2 | c.782T>A p.L261H (on ENST00000379504 / NM_001350333.2; = p.L211H on NM_001033551.3) | Missense Mutation (SNP) | VAF 130/368 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOR1AIP2 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 54/377 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TRA2B | c.292C>T p.H98Y | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TRAPPC10 | c.3044_3045del p.W1015Yfs*21 | Frame Shift Del (DEL) | VAF 59/342 reads (17%) | called by mutect2, pindel, varscan2
- TRIM42 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 265/632 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TTC3 | c.1444-1G>A p.X482_splice | Splice Site (SNP) | VAF 40/194 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.53702C>T p.S17901F (on ENST00000591111; = p.S10477F on NM_003319.4) | Missense Mutation (SNP) | VAF 50/385 reads (13%) | PolyPhen benign (0.24); called by muse, mutect2, varscan2
- TULP1 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 62/757 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.084); called by muse, mutect2
- UBASH3A | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 158/320 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- UGT2B17 | c.374T>G p.I125R | Missense Mutation (SNP) | VAF 76/113 reads (67%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- UNC80 | c.1596G>A p.M532I | Missense Mutation (SNP) | VAF 152/399 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP6 | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- VANGL2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 115/471 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- VWF | c.5450C>T p.S1817F | Missense Mutation (SNP) | VAF 117/247 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.27); called by muse, mutect2, varscan2
- WDR45 | c.298A>G p.T100A (on ENST00000376372 / NM_001029896.2; = p.T101A on NM_007075.3) | Missense Mutation (SNP) | VAF 269/352 reads (76%) | SIFT tolerated (0.35); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- WDR7 | c.4464C>A p.F1488L | Missense Mutation (SNP) | VAF 75/338 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- WDR70 | c.1637G>A p.S546N | Missense Mutation (SNP) | VAF 190/313 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- WFIKKN2 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 121/371 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP1 | c.4727G>A p.G1576E | Missense Mutation (SNP) | VAF 233/542 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZBTB37 | c.1321C>T p.Q441* | Nonsense Mutation (SNP) | VAF 62/445 reads (14%) | called by muse, mutect2, varscan2
- ZBTB8B | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 122/384 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC13 | c.1074G>A p.W358* | Nonsense Mutation (SNP) | VAF 29/297 reads (10%) | called by muse, mutect2, varscan2
- ZNF19 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- ZNF235 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 82/410 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- ZNF536 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 111/554 reads (20%) | called by muse, mutect2, varscan2
- ZNF707 | c.700T>G p.C234G | Missense Mutation (SNP) | VAF 349/786 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF746 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AC007040.2 | c.234C>T p.L78= | Silent (SNP) | VAF 51/433 reads (12%) | catalogued as rs201927886; called by muse, mutect2, varscan2
- AC099489.1 | c.2298G>A p.G766= | Silent (SNP) | VAF 203/552 reads (37%) | catalogued as rs932302222; called by muse, mutect2
- ACE2 | c.768C>T p.I256= | Silent (SNP) | VAF 163/217 reads (75%) | catalogued as rs377035576, COSV53026275; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3000G>A p.G1000= | Silent (SNP) | VAF 104/660 reads (16%) | catalogued as rs200971374, COSV65895320; called by muse, mutect2, varscan2
- ADCK1 | c.399C>T p.V133= | Silent (SNP) | VAF 46/394 reads (12%) | called by muse, mutect2, varscan2
- AGBL1 | c.2832C>T p.I944= | Silent (SNP) | VAF 80/187 reads (43%) | catalogued as COSV66853788; called by muse, mutect2, varscan2
- AGXT | c.876C>T p.R292= | Silent (SNP) | VAF 120/487 reads (25%) | catalogued as rs763852365, COSV56755607; called by muse, mutect2, varscan2
- AL645922.1 | c.2031G>A p.R677= | Silent (SNP) | VAF 274/1032 reads (27%) | called by muse, mutect2, varscan2
- AL662899.2 | c.264C>T p.I88= | Silent (SNP) | VAF 192/760 reads (25%) | catalogued as COSV65508262; called by muse, mutect2, varscan2
- ANKRD34C | c.615G>A p.K205= | Silent (SNP) | VAF 145/387 reads (37%) | called by muse, mutect2, varscan2
- APOB | c.4680C>T p.S1560= | Silent (SNP) | VAF 92/399 reads (23%) | catalogued as rs948486350, COSV51938869; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARC | c.1155C>T p.S385= | Silent (SNP) | VAF 175/495 reads (35%) | catalogued as rs767852123; called by muse, mutect2, varscan2
- AREL1 | c.966C>T p.S322= | Silent (SNP) | VAF 59/516 reads (11%) | catalogued as rs761377462, COSV62665924; called by muse, mutect2, varscan2
- ARFGEF1 | c.2083C>T p.L695= | Silent (SNP) | VAF 81/388 reads (21%) | catalogued as rs773815622; called by muse, mutect2, varscan2
- ARHGAP17 | c.138C>T p.S46= | Silent (SNP) | VAF 163/410 reads (40%) | catalogued as COSV99253306; called by muse, mutect2, varscan2
- AXIN2 | c.1284C>T p.S428= | Silent (SNP) | VAF 105/865 reads (12%) | catalogued as rs750126379; called by muse, mutect2, varscan2
- BEND4 | c.588C>T p.S196= | Silent (SNP) | VAF 79/359 reads (22%) | called by muse, varscan2
- BHLHE22 | c.849C>T p.I283= | Silent (SNP) | VAF 92/437 reads (21%) | catalogued as COSV58861435; called by muse, mutect2, varscan2
- BOLA3 | c.315C>T p.P105= | Silent (SNP) | VAF 116/483 reads (24%) | called by muse, mutect2, varscan2
- C12orf56 | c.1089C>T p.F363= (on ENST00000543942 / NM_001170633.2; = p.F203= on NM_001099676.3) | Silent (SNP) | VAF 31/223 reads (14%) | called by muse, mutect2, varscan2
- CA13 | c.468C>T p.S156= | Silent (SNP) | VAF 83/239 reads (35%) | catalogued as rs368124926; called by muse, mutect2, varscan2
- CACNA1H | c.4611C>T p.S1537= | Silent (SNP) | VAF 184/441 reads (42%) | catalogued as rs909891273, COSV61995498; called by muse, mutect2, varscan2
- CACNA2D1 | c.432G>A p.R144= | Silent (SNP) | VAF 68/394 reads (17%) | called by muse, mutect2, varscan2
- CARD10 | c.1458G>C p.L486= | Silent (SNP) | VAF 175/411 reads (43%) | called by muse, mutect2, varscan2
- CASP2 | c.597T>C p.R199= | Silent (SNP) | VAF 62/300 reads (21%) | called by muse, mutect2, varscan2
- CCDC40 | c.792C>T p.S264= | Silent (SNP) | VAF 178/510 reads (35%) | catalogued as rs755272659, COSV99482210; called by muse, varscan2
- CCL8 | c.123G>A p.R41= | Silent (SNP) | VAF 146/455 reads (32%) | catalogued as COSV67013909; called by muse, mutect2, varscan2
- CCR3 | c.825G>A p.R275= | Silent (SNP) | VAF 204/497 reads (41%) | catalogued as rs758890978; called by muse, mutect2, varscan2
- CDK2AP1 | c.135G>C p.P45= | Silent (SNP) | VAF 48/258 reads (19%) | catalogued as COSV55542674; called by muse, mutect2, varscan2
- CDKAL1 | c.399C>T p.I133= | Silent (SNP) | VAF 121/434 reads (28%) | catalogued as rs770614347, COSV51192792; called by muse, mutect2, varscan2
- CEACAM20 | c.864C>T p.F288= | Silent (SNP) | VAF 252/573 reads (44%) | called by muse, mutect2, varscan2
- CEACAM21 | c.780C>T p.L260= (on ENST00000401445 / NM_001098506.4; = p.L259= on NM_033543.6) | Silent (SNP) | VAF 151/381 reads (40%) | catalogued as COSV51814229; called by muse, mutect2, varscan2
- CEACAM5 | c.765G>T p.L255= | Silent (SNP) | VAF 79/482 reads (16%) | called by muse, mutect2, varscan2
- CEL | c.2082C>T p.P694= (on ENST00000673714; = p.P691= on NM_001807.6) | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as rs1162171285, COSV60828202; called by mutect2, varscan2
- CELSR1 | c.4323G>A p.E1441= | Silent (SNP) | VAF 70/492 reads (14%) | catalogued as COSV53082905; called by muse, mutect2, varscan2
- CHFR | c.1626T>G p.G542= (on ENST00000432561 / NM_001161345.1; = p.G501= on NM_018223.2) | Silent (SNP) | VAF 62/322 reads (19%) | called by muse, mutect2, varscan2
- CHP1 | c.393C>T p.S131= | Silent (SNP) | VAF 64/349 reads (18%) | catalogued as rs1371512467; called by muse, mutect2, varscan2
- COL28A1 | c.129C>T p.S43= | Silent (SNP) | VAF 59/171 reads (35%) | called by muse, mutect2, varscan2
- CRACD | c.1089G>A p.E363= | Silent (SNP) | VAF 86/557 reads (15%) | called by muse, mutect2, varscan2
- CREB5 | c.657C>A p.P219= (on ENST00000357727 / NM_182898.4; = p.P212= on NM_004904.3) | Silent (SNP) | VAF 62/420 reads (15%) | called by muse, mutect2, varscan2
- CRYAB | c.510C>T p.T170= | Silent (SNP) | VAF 44/259 reads (17%) | catalogued as rs147970333, COSV99909912; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSF2RA | c.708G>A p.R236= | Silent (SNP) | VAF 98/691 reads (14%) | catalogued as rs749330435; called by muse, mutect2, varscan2
- CSMD1 | c.2988C>T p.P996= (on ENST00000520002; = p.P995= on NM_033225.6) | Silent (SNP) | VAF 158/412 reads (38%) | catalogued as rs1396332781, COSV59300813, COSV59335872; called by muse, varscan2
- CYP2C9 | c.402T>C p.F134= | Silent (SNP) | VAF 54/462 reads (12%) | called by muse, mutect2, varscan2
- CYP2D7 | c.336C>T p.F112= | Silent (SNP) | VAF 109/466 reads (23%) | catalogued as rs1418591609; called by muse, mutect2, varscan2
- CYP2E1 | c.441C>T p.I147= | Silent (SNP) | VAF 55/346 reads (16%) | called by muse, mutect2, varscan2
- DCC | c.2280C>T p.I760= | Silent (SNP) | VAF 90/405 reads (22%) | catalogued as rs201276568, COSV100499079, COSV59089648; called by muse, mutect2, varscan2
- DEFB104A | c.105C>T p.A35= | Silent (SNP) | VAF 59/263 reads (22%) | called by muse, mutect2, varscan2
- DNAAF1 | c.276C>T p.S92= | Silent (SNP) | VAF 50/283 reads (18%) | called by muse, mutect2, varscan2
- DNAH11 | c.8121C>T p.I2707= | Silent (SNP) | VAF 34/356 reads (10%) | catalogued as rs1281532213; called by muse, mutect2, varscan2
- DNAH6 | c.8046G>A p.R2682= | Silent (SNP) | VAF 77/185 reads (42%) | catalogued as COSV52851332; called by muse, mutect2, varscan2
- DOP1B | c.1419C>T p.P473= | Silent (SNP) | VAF 232/473 reads (49%) | catalogued as rs199879429; called by muse, mutect2, varscan2
- EFHB | c.1152G>A p.T384= | Silent (SNP) | VAF 97/239 reads (41%) | catalogued as rs1427596034, COSV55546669; called by muse, mutect2
- EHD3 | c.1092G>A p.Q364= | Silent (SNP) | VAF 47/252 reads (19%) | called by muse, mutect2, varscan2
- EIF3H | c.502A>C p.R168= | Silent (SNP) | VAF 87/397 reads (22%) | called by muse, mutect2, varscan2
- ELL | c.213C>T p.P71= | Silent (SNP) | VAF 85/384 reads (22%) | catalogued as rs367638746; called by muse, mutect2, varscan2
- EPHA8 | c.1782C>T p.F594= | Silent (SNP) | VAF 70/275 reads (25%) | catalogued as rs750902137, COSV51272084; called by muse, mutect2, varscan2
- EXOC4 | c.501C>T p.P167= | Silent (SNP) | VAF 105/267 reads (39%) | called by muse, mutect2, varscan2
- FADS3 | c.1005C>T p.F335= | Silent (SNP) | VAF 135/340 reads (40%) | catalogued as rs111249700, COSV53879798; called by muse, mutect2, varscan2
- FAM187A | c.1065C>T p.F355= | Silent (SNP) | VAF 182/502 reads (36%) | catalogued as rs1406282307; called by muse, mutect2, varscan2
- FARP2 | c.1602C>T p.D534= | Silent (SNP) | VAF 64/412 reads (16%) | catalogued as rs755476112, COSV50882073; called by muse, mutect2, varscan2
- FFAR2 | c.255G>A p.T85= | Silent (SNP) | VAF 76/566 reads (13%) | catalogued as rs1364784849, COSV55833009; called by muse, mutect2, varscan2
- FLT4 | c.3951G>A p.G1317= | Silent (SNP) | VAF 380/548 reads (69%) | catalogued as COSV99988287; called by muse, mutect2, varscan2
- FOXK2 | c.735G>A p.K245= | Silent (SNP) | VAF 146/400 reads (37%) | called by muse, mutect2, varscan2
- FSIP2 | c.11814C>T p.S3938= | Silent (SNP) | VAF 78/345 reads (23%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.711C>T p.L237= | Silent (SNP) | VAF 226/507 reads (45%) | catalogued as rs768259905, COSV61749107; called by muse, mutect2, varscan2
- GATAD2B | c.117C>T p.A39= | Silent (SNP) | VAF 87/683 reads (13%) | catalogued as rs1219732783; called by muse, mutect2, varscan2
- GDAP1L1 | c.570G>A p.T190= | Silent (SNP) | VAF 148/433 reads (34%) | catalogued as rs375517198; called by muse, mutect2, varscan2
- GGTLC2 | c.432G>A p.V144= | Silent (SNP) | VAF 95/390 reads (24%) | called by muse, mutect2, varscan2
- GPR17 | c.915G>A p.L305= | Silent (SNP) | VAF 96/687 reads (14%) | catalogued as rs779544947; called by muse, mutect2, varscan2
- GPR26 | c.951C>T p.S317= | Silent (SNP) | VAF 63/343 reads (18%) | catalogued as COSV52933823; called by muse, mutect2, varscan2
- GPR45 | c.699G>A p.S233= | Silent (SNP) | VAF 128/579 reads (22%) | catalogued as rs371966047; called by muse, mutect2, varscan2
- GRM3 | c.576C>T p.P192= | Silent (SNP) | VAF 134/339 reads (40%) | catalogued as rs368299243; called by muse, mutect2, varscan2
- HAGHL | c.36C>T p.N12= | Silent (SNP) | VAF 51/374 reads (14%) | called by muse, mutect2, varscan2
- HECTD4 | c.6183G>A p.S2061= | Silent (SNP) | VAF 45/275 reads (16%) | catalogued as rs371484131; called by muse, mutect2, varscan2
- HLA-DQB2 | c.120G>A p.K40= | Silent (SNP) | VAF 404/720 reads (56%) | called by muse, mutect2, varscan2
- HMOX2 | c.243C>T p.L81= | Silent (SNP) | VAF 173/448 reads (39%) | catalogued as rs1295363769; called by muse, varscan2
- IKZF4 | c.216C>T p.L72= | Silent (SNP) | VAF 192/398 reads (48%) | catalogued as rs778322454; called by muse, mutect2, varscan2
- IL24 | c.351G>A p.L117= | Silent (SNP) | VAF 161/387 reads (42%) | catalogued as COSV54321774; called by muse, mutect2, varscan2
- IL2RG | c.786C>T p.A262= | Silent (SNP) | VAF 57/275 reads (21%) | catalogued as rs374370835; ClinVar: benign; called by muse, mutect2, varscan2
- ILF3 | c.306C>T p.L102= | Silent (SNP) | VAF 168/469 reads (36%) | called by muse, mutect2, varscan2
- ILF3 | c.307C>T p.L103= | Silent (SNP) | VAF 165/464 reads (36%) | called by muse, mutect2, varscan2
- IPPK | c.669C>T p.A223= | Silent (SNP) | VAF 67/380 reads (18%) | called by muse, mutect2, varscan2
- IQGAP1 | c.4149C>T p.T1383= | Silent (SNP) | VAF 46/321 reads (14%) | called by muse, mutect2, varscan2
- IRS1 | c.1641C>T p.S547= | Silent (SNP) | VAF 59/411 reads (14%) | called by muse, mutect2, varscan2
- KCNQ3 | c.675C>T p.S225= | Silent (SNP) | VAF 115/477 reads (24%) | catalogued as rs921121642, COSV66480546; called by muse, mutect2, varscan2
- KDM5C | c.777G>A p.K259= | Silent (SNP) | VAF 69/277 reads (25%) | called by muse, mutect2, varscan2
- KIAA1549 | c.2910C>T p.I970= | Silent (SNP) | VAF 122/325 reads (38%) | called by muse, mutect2, varscan2
- KLF17 | c.447G>A p.G149= | Silent (SNP) | VAF 109/342 reads (32%) | catalogued as COSV64856990; called by muse, mutect2, varscan2
- KRT20 | c.45C>T p.S15= | Silent (SNP) | VAF 203/605 reads (34%) | called by muse, mutect2, varscan2
- KRT6B | c.703C>T p.L235= | Silent (SNP) | VAF 65/636 reads (10%) | called by muse, mutect2, varscan2
- LAMB2 | c.1689C>T p.F563= | Silent (SNP) | VAF 152/617 reads (25%) | called by muse, mutect2, varscan2
- LGI1 | c.1488C>T p.Y496= | Silent (SNP) | VAF 66/289 reads (23%) | called by muse, mutect2, varscan2
- LIMS1 | c.69C>T p.I23= | Silent (SNP) | VAF 208/892 reads (23%) | catalogued as rs375236817; called by muse, mutect2, varscan2
- LPIN3 | c.525C>T p.S175= | Silent (SNP) | VAF 125/383 reads (33%) | called by muse, mutect2, varscan2
- MACC1 | c.1776C>T p.S592= | Silent (SNP) | VAF 153/458 reads (33%) | catalogued as rs1402895358; called by muse, mutect2, varscan2
- MAP3K6 | c.2265C>T p.I755= | Silent (SNP) | VAF 61/378 reads (16%) | catalogued as rs1557560134, COSV62890121; called by muse, mutect2, varscan2
- MARCHF10 | c.681C>T p.S227= | Silent (SNP) | VAF 184/538 reads (34%) | called by muse, mutect2, varscan2
- MB21D2 | c.1137C>T p.I379= | Silent (SNP) | VAF 161/553 reads (29%) | catalogued as rs777147620; called by muse, mutect2, varscan2
- MICALL1 | c.378C>T p.S126= | Silent (SNP) | VAF 76/285 reads (27%) | called by muse, mutect2, varscan2
- MORC1 | c.369G>A p.T123= | Silent (SNP) | VAF 145/386 reads (38%) | catalogued as rs373682179; called by muse, mutect2, varscan2
- MRPS12 | c.352C>T p.L118= | Silent (SNP) | VAF 81/382 reads (21%) | called by muse, varscan2
- MT2A | c.90G>A p.K30= | Silent (SNP) | VAF 81/340 reads (24%) | catalogued as rs748340093; called by muse, mutect2, varscan2
- MUC16 | c.21657G>A p.E7219= | Silent (SNP) | VAF 178/412 reads (43%) | called by muse, mutect2, varscan2
- MUC16 | c.21210G>A p.E7070= | Silent (SNP) | VAF 89/397 reads (22%) | catalogued as rs774903170, COSV101202126; called by muse, mutect2, varscan2
- MUC16 | c.11898C>T p.S3966= | Silent (SNP) | VAF 168/467 reads (36%) | catalogued as COSV101201500; called by muse, mutect2
- MUC16 | c.1281G>A p.K427= | Silent (SNP) | VAF 157/364 reads (43%) | catalogued as rs751891780; called by muse, mutect2, varscan2
- MYH1 | c.48C>T p.F16= | Silent (SNP) | VAF 126/396 reads (32%) | called by muse, mutect2, varscan2
- MYH15 | c.4815C>T p.T1605= | Silent (SNP) | VAF 155/351 reads (44%) | called by muse, mutect2, varscan2
- MYH4 | c.4794G>A p.V1598= | Silent (SNP) | VAF 150/396 reads (38%) | called by muse, varscan2
- MYH6 | c.1398C>T p.F466= | Silent (SNP) | VAF 70/474 reads (15%) | catalogued as rs745448722, COSV62448949; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO9B | c.4440G>A p.G1480= | Silent (SNP) | VAF 58/458 reads (13%) | catalogued as rs1274068667; called by muse, mutect2, varscan2
- NEB | c.11175C>T p.I3725= | Silent (SNP) | VAF 37/268 reads (14%) | called by muse, mutect2, varscan2
- NGF | c.42C>T p.I14= | Silent (SNP) | VAF 140/301 reads (47%) | catalogued as rs752800027, COSV65687643; called by muse, mutect2, varscan2
- NLRP5 | c.957C>T p.L319= | Silent (SNP) | VAF 188/414 reads (45%) | called by muse, mutect2, varscan2
- NLRP7 | c.1395C>T p.S465= | Silent (SNP) | VAF 156/701 reads (22%) | catalogued as COSV60176915; called by muse, mutect2, varscan2
- NOS1AP | c.828G>A p.S276= | Silent (SNP) | VAF 53/452 reads (12%) | catalogued as rs756068745, COSV62633189; called by muse, varscan2
- NOS2 | c.696T>C p.R232= | Silent (SNP) | VAF 174/496 reads (35%) | called by muse, mutect2
- NPAP1 | c.285G>A p.R95= | Silent (SNP) | VAF 110/565 reads (19%) | catalogued as COSV61510930; called by muse, mutect2, varscan2
- NPAP1 | c.2037C>T p.S679= | Silent (SNP) | VAF 63/411 reads (15%) | catalogued as COSV100276383; called by muse, mutect2, varscan2
- NPAP1 | c.2154G>A p.K718= | Silent (SNP) | VAF 171/406 reads (42%) | catalogued as COSV100275159; called by muse, mutect2, varscan2
- NPHS1 | c.3579C>T p.Y1193= | Silent (SNP) | VAF 61/265 reads (23%) | catalogued as rs747950877, COSV62286104; called by muse, mutect2, varscan2
- NPPA | c.402G>A p.R134= | Silent (SNP) | VAF 97/329 reads (29%) | called by muse, mutect2, varscan2
- NR4A2 | c.1095C>T p.I365= | Silent (SNP) | VAF 58/454 reads (13%) | called by muse, mutect2, varscan2
- NUF2 | c.498G>A p.L166= | Silent (SNP) | VAF 96/242 reads (40%) | catalogued as rs1467454730; called by muse, mutect2, varscan2
- NUP37 | c.954G>A p.K318= | Silent (SNP) | VAF 37/278 reads (13%) | called by muse, mutect2, varscan2
- NUP98 | c.2757G>A p.Q919= | Silent (SNP) | VAF 78/487 reads (16%) | catalogued as COSV100263300; called by muse, mutect2
- OBSCN | c.480G>A p.V160= | Silent (SNP) | VAF 134/637 reads (21%) | called by muse, mutect2, varscan2
- OR10A7 | c.603C>T p.A201= | Silent (SNP) | VAF 61/285 reads (21%) | called by muse, mutect2, varscan2
- OR1B1 | c.810C>T p.F270= | Silent (SNP) | VAF 218/358 reads (61%) | called by muse, mutect2
- OR1D5 | c.582C>A p.I194= | Silent (SNP) | VAF 40/520 reads (8%) | called by muse, mutect2
- OR2T34 | c.405C>T p.L135= | Silent (SNP) | VAF 91/264 reads (34%) | called by muse, mutect2, varscan2
- OR4D5 | c.745T>C p.L249= | Silent (SNP) | VAF 67/427 reads (16%) | called by muse, mutect2, varscan2
- OR4K1 | c.696G>A p.G232= | Silent (SNP) | VAF 43/331 reads (13%) | catalogued as rs745782778; called by muse, mutect2, varscan2
- OR4K13 | c.444C>T p.S148= | Silent (SNP) | VAF 143/414 reads (35%) | catalogued as COSV100237746; called by muse, mutect2, varscan2
- OR4L1 | c.888G>A p.E296= | Silent (SNP) | VAF 86/314 reads (27%) | catalogued as rs1333713171; called by muse, mutect2
- OR51M1 | c.381C>T p.L127= | Silent (SNP) | VAF 106/487 reads (22%) | catalogued as rs776328978, COSV60785050; called by muse, mutect2, varscan2
- OR6Y1 | c.723G>A p.K241= | Silent (SNP) | VAF 153/380 reads (40%) | catalogued as rs887909279; called by muse, mutect2, varscan2
- OR8D2 | c.771C>T p.F257= | Silent (SNP) | VAF 82/350 reads (23%) | called by muse, mutect2, varscan2
- OR9H1P | c.321C>T p.I107= | Silent (SNP) | VAF 92/355 reads (26%) | called by muse, mutect2, varscan2
- OVGP1 | c.822G>A p.K274= | Silent (SNP) | VAF 160/397 reads (40%) | called by muse, mutect2, varscan2
- P2RY10 | c.729G>A p.R243= | Silent (SNP) | VAF 223/303 reads (74%) | catalogued as rs1382166632; called by muse, mutect2, varscan2
- PAK5 | c.1011G>A p.Q337= | Silent (SNP) | VAF 122/501 reads (24%) | catalogued as COSV62031382; called by muse, mutect2, varscan2
- PAQR9 | c.720C>T p.F240= | Silent (SNP) | VAF 260/721 reads (36%) | catalogued as rs758925968; called by muse, mutect2, varscan2
- PHKG1 | c.909G>A p.G303= | Silent (SNP) | VAF 108/295 reads (37%) | catalogued as rs1051312547; called by muse, mutect2, varscan2
- PHLPP2 | c.3390G>A p.Q1130= | Silent (SNP) | VAF 93/424 reads (22%) | called by muse, mutect2, varscan2
- PLCD3 | c.351C>T p.V117= | Silent (SNP) | VAF 64/800 reads (8%) | catalogued as rs758644247; called by muse, mutect2
- PLCG2 | c.1788C>T p.T596= | Silent (SNP) | VAF 216/500 reads (43%) | called by muse, mutect2, varscan2
- PNPLA1 | c.267C>A p.P89= | Silent (SNP) | VAF 64/630 reads (10%) | called by muse, mutect2, varscan2
- POTEE | c.2859G>A p.E953= | Silent (SNP) | VAF 210/1392 reads (15%) | catalogued as rs1490114091; called by muse, mutect2
- PPAN-P2RY11 | c.261C>T p.I87= | Silent (SNP) | VAF 52/364 reads (14%) | called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.262C>T p.L88= | Silent (SNP) | VAF 52/361 reads (14%) | called by muse, mutect2, varscan2
- PRG2 | c.120G>A p.E40= | Silent (SNP) | VAF 75/518 reads (14%) | called by muse, mutect2, varscan2
- PROX2 | c.1389G>A p.L463= | Silent (SNP) | VAF 33/434 reads (8%) | called by muse, mutect2
- PSG1 | c.9C>T p.T3= | Silent (SNP) | VAF 58/304 reads (19%) | catalogued as COSV54944119; called by muse, mutect2, varscan2
- PSME4 | c.4897T>C p.L1633= | Silent (SNP) | VAF 108/293 reads (37%) | called by muse, mutect2, varscan2
- PTPN20 | c.30G>A p.E10= | Silent (SNP) | VAF 65/1002 reads (6%) | called by muse, mutect2
- PTPRN2 | c.1761G>A p.L587= | Silent (SNP) | VAF 74/349 reads (21%) | catalogued as COSV67027970; called by muse, mutect2, varscan2
- PXDN | c.3651C>G p.L1217= | Silent (SNP) | VAF 133/345 reads (39%) | called by muse, mutect2, varscan2
- RAI1 | c.2712G>A p.V904= | Silent (SNP) | VAF 65/766 reads (8%) | catalogued as rs534150897; called by muse, mutect2
- REXO5 | c.1413C>T p.P471= | Silent (SNP) | VAF 130/314 reads (41%) | called by muse, mutect2, varscan2
- RFC2 | c.774C>T p.P258= (on ENST00000055077 / NM_181471.3; = p.P224= on NM_002914.4) | Silent (SNP) | VAF 36/254 reads (14%) | called by muse, mutect2, varscan2
- RNPS1 | c.843C>T p.S281= | Silent (SNP) | VAF 175/403 reads (43%) | catalogued as rs1249256274; called by muse, mutect2, varscan2
- RRP12 | c.3024C>T p.F1008= | Silent (SNP) | VAF 73/444 reads (16%) | called by muse, mutect2, varscan2
- RYR2 | c.11173C>T p.L3725= | Silent (SNP) | VAF 42/290 reads (14%) | catalogued as COSV63680234; called by muse, mutect2, varscan2
- RYR3 | c.888C>T p.A296= | Silent (SNP) | VAF 98/416 reads (24%) | called by muse, mutect2, varscan2
- RYR3 | c.4584C>T p.P1528= | Silent (SNP) | VAF 110/458 reads (24%) | catalogued as rs1451632299, COSV66778911; called by muse, varscan2
- RYR3 | c.10953G>A p.G3651= (on ENST00000389232; = p.G3652= on NM_001036.6) | Silent (SNP) | VAF 172/345 reads (50%) | called by muse, mutect2, varscan2
- RYR3 | c.11694G>T p.L3898= (on ENST00000389232; = p.L3899= on NM_001036.6) | Silent (SNP) | VAF 58/335 reads (17%) | called by muse, mutect2, varscan2
- S100A14 | c.306G>A p.R102= | Silent (SNP) | VAF 111/245 reads (45%) | catalogued as rs1193108582; called by muse, mutect2, varscan2
- S1PR5 | c.444G>A p.R148= | Silent (SNP) | VAF 95/657 reads (14%) | called by muse, mutect2, varscan2
- SAMD9 | c.3261G>A p.A1087= | Silent (SNP) | VAF 66/358 reads (18%) | catalogued as rs372006940, COSV66075541; called by muse, mutect2, varscan2
- SBK3 | c.720C>T p.F240= | Silent (SNP) | VAF 122/594 reads (21%) | called by muse, mutect2, varscan2
- SBK3 | c.348C>T p.F116= | Silent (SNP) | VAF 132/553 reads (24%) | catalogued as rs992484346; called by muse, mutect2, varscan2
- SCFD2 | c.1302C>T p.L434= | Silent (SNP) | VAF 105/252 reads (42%) | called by muse, mutect2, varscan2
- SEMA3E | c.1923C>T p.F641= | Silent (SNP) | VAF 79/351 reads (23%) | catalogued as COSV57090640; called by muse, mutect2, varscan2
- SFMBT2 | c.825C>T p.S275= | Silent (SNP) | VAF 76/370 reads (21%) | called by muse, mutect2, varscan2
- SGCA | c.1065G>A p.R355= | Silent (SNP) | VAF 246/729 reads (34%) | catalogued as rs1341399668; called by muse, mutect2, varscan2
- SH3D19 | c.1863C>T p.P621= | Silent (SNP) | VAF 85/373 reads (23%) | called by muse, mutect2, varscan2
- SH3TC1 | c.3153C>T p.D1051= | Silent (SNP) | VAF 74/304 reads (24%) | catalogued as rs373577257; called by muse, mutect2, varscan2
- SI | c.3309G>A p.S1103= | Silent (SNP) | VAF 189/446 reads (42%) | catalogued as rs765589827, COSV100017295; called by muse, mutect2, varscan2
- SIGLECL1 | c.45C>T p.S15= | Silent (SNP) | VAF 45/248 reads (18%) | called by muse, mutect2, varscan2
- SIRT1 | c.681C>T p.I227= | Silent (SNP) | VAF 62/251 reads (25%) | catalogued as COSV99281650; called by muse, mutect2, varscan2
- SLC13A2 | c.1008C>T p.F336= | Silent (SNP) | VAF 217/635 reads (34%) | catalogued as rs868952819, COSV58993921; called by muse, mutect2, varscan2
- SLC25A20 | c.729G>A p.G243= | Silent (SNP) | VAF 54/287 reads (19%) | called by muse, mutect2, varscan2
- SLC35F2 | c.375C>T p.I125= | Silent (SNP) | VAF 152/326 reads (47%) | catalogued as rs773395067, COSV56183080; called by muse, mutect2, varscan2
- SLC39A14 | c.792C>T p.P264= | Silent (SNP) | VAF 44/354 reads (12%) | called by muse, mutect2
- SLC41A2 | c.1545C>T p.T515= | Silent (SNP) | VAF 44/216 reads (20%) | catalogued as COSV51605911, COSV99316767; called by muse, mutect2, varscan2
- SLC6A2 | c.1362C>T p.F454= | Silent (SNP) | VAF 173/304 reads (57%) | called by muse, mutect2, varscan2
- SLC6A3 | c.216C>T p.S72= | Silent (SNP) | VAF 449/680 reads (66%) | catalogued as rs373050350; called by muse, mutect2, varscan2
- SLC7A14 | c.1824C>T p.I608= | Silent (SNP) | VAF 307/698 reads (44%) | called by muse, mutect2, varscan2
- SLC7A8 | c.1248C>T p.I416= | Silent (SNP) | VAF 152/398 reads (38%) | catalogued as rs753488263, COSV57552902; called by muse, mutect2, varscan2
- SLIT1 | c.1593C>T p.L531= | Silent (SNP) | VAF 67/464 reads (14%) | called by muse, mutect2, varscan2
- SLIT3 | c.1644G>A p.E548= | Silent (SNP) | VAF 183/294 reads (62%) | called by muse, mutect2, varscan2
- SMG5 | c.2166C>T p.L722= | Silent (SNP) | VAF 56/412 reads (14%) | called by muse, mutect2, varscan2
- SNX29 | c.801C>T p.I267= | Silent (SNP) | VAF 162/355 reads (46%) | called by muse, mutect2, varscan2
- SPHKAP | c.609G>A p.T203= | Silent (SNP) | VAF 182/439 reads (41%) | catalogued as rs1246576109, COSV60869524; called by muse, mutect2, varscan2
- SRC | c.1096C>T p.L366= | Silent (SNP) | VAF 186/521 reads (36%) | called by muse, mutect2, varscan2
- SRGAP3 | c.3132C>T p.S1044= | Silent (SNP) | VAF 237/595 reads (40%) | catalogued as rs748187826; ClinVar: likely benign; called by muse, mutect2, varscan2
- SRPK1 | c.879G>A p.E293= | Silent (SNP) | VAF 221/806 reads (27%) | called by muse, mutect2, varscan2
- STK38 | c.408G>A p.A136= | Silent (SNP) | VAF 114/507 reads (22%) | catalogued as rs1429746464; called by muse, mutect2, varscan2
- STOX2 | c.2295G>A p.G765= | Silent (SNP) | VAF 71/421 reads (17%) | called by muse, mutect2, varscan2
- SUN5 | c.438G>A p.E146= | Silent (SNP) | VAF 133/423 reads (31%) | called by muse, mutect2, varscan2
- SV2A | c.288G>A p.G96= | Silent (SNP) | VAF 234/535 reads (44%) | called by muse, mutect2, varscan2
- SYNE1 | c.24798G>A p.R8266= (on ENST00000367255 / NM_182961.4; = p.R8195= on NM_033071.3) | Silent (SNP) | VAF 58/318 reads (18%) | called by muse, mutect2, varscan2
- TAF1C | c.1623C>T p.D541= | Silent (SNP) | VAF 176/444 reads (40%) | catalogued as rs767803386; called by muse, mutect2, varscan2
- TAF3 | c.525C>T p.F175= | Silent (SNP) | VAF 74/336 reads (22%) | catalogued as rs1175864993; called by muse, mutect2, varscan2
- TAS2R39 | c.222G>A p.R74= | Silent (SNP) | VAF 63/427 reads (15%) | catalogued as COSV101489413; called by muse, mutect2, varscan2
- TAS2R41 | c.672C>T p.P224= | Silent (SNP) | VAF 184/442 reads (42%) | called by muse, mutect2, varscan2
- TBC1D10C | c.768C>T p.F256= | Silent (SNP) | VAF 127/618 reads (21%) | catalogued as COSV56705195; called by muse, mutect2, varscan2
- TELO2 | c.1095C>T p.L365= | Silent (SNP) | VAF 266/610 reads (44%) | catalogued as rs780757073; called by muse, mutect2, varscan2
- TENM4 | c.6363G>A p.G2121= | Silent (SNP) | VAF 196/462 reads (42%) | catalogued as rs779128065; called by muse, mutect2, varscan2
- TFAP4 | c.210C>T p.S70= | Silent (SNP) | VAF 86/373 reads (23%) | catalogued as COSV52597876; called by muse, mutect2, varscan2
- TIE1 | c.144C>T p.A48= | Silent (SNP) | VAF 86/488 reads (18%) | catalogued as rs750143000; called by muse, mutect2, varscan2
- TM4SF5 | c.363C>T p.N121= | Silent (SNP) | VAF 31/529 reads (6%) | catalogued as rs756181828, COSV54496132; called by muse, mutect2
- TMC2 | c.1539C>T p.F513= | Silent (SNP) | VAF 144/586 reads (25%) | catalogued as COSV62656386; called by muse, mutect2, varscan2
- TMEM265 | c.195C>T p.S65= | Silent (SNP) | VAF 88/441 reads (20%) | catalogued as rs1458227412; called by muse, mutect2, varscan2
- TOR1AIP2 | c.966C>T p.S322= | Silent (SNP) | VAF 54/376 reads (14%) | catalogued as rs1327053680; called by muse, mutect2, varscan2
- TRANK1 | c.7161C>T p.F2387= | Silent (SNP) | VAF 67/402 reads (17%) | catalogued as COSV100082109; called by muse, mutect2, varscan2
- TRAPPC12 | c.780C>T p.P260= | Silent (SNP) | VAF 235/578 reads (41%) | catalogued as rs1350381543, COSV60852740; called by muse, mutect2, varscan2
- TRERF1 | c.1599C>T p.S533= | Silent (SNP) | VAF 331/620 reads (53%) | called by muse, mutect2, varscan2
- TRIM67 | c.1863C>A p.I621= | Silent (SNP) | VAF 40/329 reads (12%) | catalogued as rs763048501; called by muse, mutect2, varscan2
- TTC28 | c.2559C>T p.A853= | Silent (SNP) | VAF 188/424 reads (44%) | called by muse, mutect2, varscan2
- TTC28 | c.1182C>T p.A394= | Silent (SNP) | VAF 227/542 reads (42%) | called by muse, mutect2, varscan2
- TTN | c.42673C>T p.L14225= (on ENST00000591111; = p.L6801= on NM_003319.4) | Silent (SNP) | VAF 28/282 reads (10%) | called by muse, mutect2
- TTN | c.16245C>T p.F5415= (on ENST00000591111; = p.F4488= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 60/276 reads (22%) | catalogued as COSV100596679; called by muse, mutect2, varscan2
- TUBA3C | c.1254C>T p.F418= | Silent (SNP) | VAF 60/553 reads (11%) | catalogued as COSV68029311; called by muse, mutect2, varscan2
- TXLNB | c.1500G>A p.V500= | Silent (SNP) | VAF 160/298 reads (54%) | catalogued as rs973437196, COSV64443574; called by muse, mutect2, varscan2
- TXNDC2 | c.951C>T p.S317= (on ENST00000306084 / NM_001098529.2; = p.S250= on NM_032243.6) | Silent (SNP) | VAF 124/702 reads (18%) | called by muse, mutect2, varscan2
- TYW1B | c.1845C>T p.I615= | Silent (SNP) | VAF 34/312 reads (11%) | called by muse, mutect2, varscan2
- UPK3BL2 | c.178C>T p.L60= | Silent (SNP) | VAF 54/742 reads (7%) | called by muse, mutect2
- UQCC1 | c.246C>T p.S82= | Silent (SNP) | VAF 95/309 reads (31%) | catalogued as COSV62902011; called by muse, mutect2, varscan2
- USP6 | c.2064A>G p.Q688= | Silent (SNP) | VAF 181/550 reads (33%) | called by muse, mutect2, varscan2
- VGF | c.156G>A p.K52= | Silent (SNP) | VAF 109/710 reads (15%) | catalogued as rs780164922; called by muse, mutect2, varscan2
- VPS52 | c.108C>T p.L36= | Silent (SNP) | VAF 76/847 reads (9%) | called by muse, mutect2
- VWA3B | c.2730C>T p.P910= | Silent (SNP) | VAF 179/458 reads (39%) | called by muse, mutect2, varscan2
- VWA5B1 | c.3363C>T p.S1121= (on ENST00000375079; = p.S1116= on NM_001039500.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 66/399 reads (17%) | called by muse, mutect2, varscan2
- VWCE | c.2569C>T p.L857= | Silent (SNP) | VAF 61/452 reads (13%) | catalogued as COSV57113640, COSV57113747; called by muse, mutect2, varscan2
- WDFY4 | c.1371C>T p.F457= | Silent (SNP) | VAF 90/395 reads (23%) | catalogued as rs767767458, COSV57428372; called by muse, mutect2, varscan2
- WDR64 | c.2541C>T p.F847= | Silent (SNP) | VAF 48/346 reads (14%) | catalogued as COSV63795755; called by muse, mutect2, varscan2
- XIRP2 | c.9450C>T p.F3150= (on ENST00000628543; = p.F3325= on NM_152381.6) | Silent (SNP) | VAF 166/359 reads (46%) | catalogued as rs1553505593, COSV54686043, COSV54714181; called by muse, mutect2, varscan2
- ZAN | c.2913C>T p.I971= | Silent (SNP) | VAF 272/618 reads (44%) | catalogued as rs772624007; called by muse, mutect2, varscan2
- ZFHX3 | c.2766G>A p.L922= | Silent (SNP) | VAF 75/436 reads (17%) | catalogued as rs757686484; called by muse, mutect2, varscan2
- ZNF331 | c.1308G>A p.A436= | Silent (SNP) | VAF 152/344 reads (44%) | catalogued as rs757099778, COSV53480824; called by muse, mutect2, varscan2
- ZNF418 | c.1407C>T p.L469= | Silent (SNP) | VAF 56/450 reads (12%) | catalogued as COSV68675579; called by muse, mutect2, varscan2
- ZNF589 | c.243C>T p.V81= | Silent (SNP) | VAF 53/247 reads (21%) | catalogued as rs1463475370; called by muse, mutect2, varscan2
- ZNF628 | c.2718C>T p.P906= | Silent (SNP) | VAF 136/639 reads (21%) | catalogued as rs1471532524; called by muse, mutect2, varscan2
- ZNF746 | c.426C>T p.P142= | Silent (SNP) | VAF 26/244 reads (11%) | catalogued as rs751295671, COSV61408736; called by muse, mutect2, varscan2
- ZNF764 | c.1098G>A p.R366= | Silent (SNP) | VAF 133/724 reads (18%) | called by muse, mutect2, varscan2
- ZNF781 | c.414C>T p.F138= | Silent (SNP) | VAF 156/413 reads (38%) | catalogued as COSV62202279; called by muse, mutect2, varscan2
- ZNF836 | c.522T>C p.S174= | Silent (SNP) | VAF 132/279 reads (47%) | called by muse, mutect2, varscan2
- ZXDA | c.2190A>T p.T730= | Silent (SNP) | VAF 97/341 reads (28%) | called by muse, mutect2, varscan2
- ZZEF1 | c.1761T>C p.I587= | Silent (SNP) | VAF 102/274 reads (37%) | called by muse, mutect2, varscan2
- AC010542.3 | c.149-12099C>T | Intron (SNP) | VAF 128/525 reads (24%) | called by muse, mutect2, varscan2
- ASF1B | c.402+20C>T | Intron (SNP) | VAF 127/562 reads (23%) | catalogued as rs551592911; called by muse, mutect2, varscan2
- CASR | c.1378-6094C>T | Intron (SNP) | VAF 118/303 reads (39%) | called by muse, mutect2, varscan2
- CSMD3 | c.*1647C>T | 3'UTR (SNP) | VAF 47/199 reads (24%) | called by muse, mutect2, varscan2
- DNAH10 | c.13307-475G>A | Intron (SNP) | VAF 84/397 reads (21%) | called by muse, mutect2, varscan2
- EVL | c.352+9595C>T | Intron (SNP) | VAF 59/503 reads (12%) | catalogued as rs1018288123; called by muse, mutect2, varscan2
- GAS8 | chr16:90020113 G>T | 5'Flank (SNP) | VAF 76/341 reads (22%) | called by muse, mutect2, varscan2
- GFM1 | c.689+847G>A | Intron (SNP) | VAF 103/404 reads (25%) | called by muse, mutect2, varscan2
- GHDC | c.1289-78A>G | Intron (SNP) | VAF 104/367 reads (28%) | called by muse, mutect2, varscan2
- GRIK3 | c.2565+47C>T | Intron (SNP) | VAF 98/333 reads (29%) | catalogued as rs776657718, COSV100901710; called by muse, mutect2, varscan2
- HSPB7 | chr1:16019230 C>T | 5'Flank (SNP) | VAF 104/362 reads (29%) | catalogued as COSV58893453; called by muse, mutect2, varscan2
- IL6 | c.471+73G>A | Intron (SNP) | VAF 48/580 reads (8%) | called by muse, mutect2
- IL6 | c.471+74G>A | Intron (SNP) | VAF 47/576 reads (8%) | catalogued as rs758741386; called by muse, mutect2
- KCNQ1 | c.1393+19707G>A | Intron (SNP) | VAF 59/331 reads (18%) | called by muse, mutect2, varscan2
- KIF18B | c.1239-31C>G | Intron (SNP) | VAF 56/301 reads (19%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-991G>A | Intron (SNP) | VAF 242/1079 reads (22%) | called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442963 T>A | 3'Flank (SNP) | VAF 103/349 reads (30%) | called by muse, mutect2, varscan2
10 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 10 other) are not listed here.
